Somatic mutation profile of tumor specimen TCGA-SA-A6C2-01A (aliquot TCGA-SA-A6C2-01A-11D-A35I-08) from TCGA case TCGA-SA-A6C2, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 46.0 years (16,805 days).
Specimen TCGA-SA-A6C2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d332675-57fb-45bf-8355-35427a995668.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SA-A6C2-10A (Blood Derived Normal), aliquot TCGA-SA-A6C2-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbbad266-a0b2-4eb3-9374-31fc5c066c35

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4, Nonsense Mutation 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 36/115 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- ARHGAP39 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV52775248; called by muse, mutect2, varscan2
- KIR2DS4 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 11/302 reads (4%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.189); catalogued as rs372124222; called by muse, mutect2
- LCT | c.4171C>T p.Q1391* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as rs868614152; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1754T>C p.I585T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | PolyPhen probably damaging (0.978); catalogued as COSV50073728; called by muse, mutect2, varscan2
- TRIM62 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52221226; called by muse, mutect2, varscan2
- USP32 | c.1399A>G p.T467A | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs1404472735, COSV56275276; called by muse, mutect2, varscan2
- AKAP5 | c.1162T>G p.Y388D | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CA2 | c.650T>A p.V217D | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CACNA1D | c.2465A>G p.D822G (on ENST00000350061 / NM_001128840.3; = p.D842G on NM_000720.4) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- ELFN2 | c.1620G>C p.E540D | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FBF1 | c.2162A>C p.D721A (on ENST00000586717; = p.D735A on NM_001319193.1) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- GRIP1 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- MTREX | c.1907T>G p.L636W | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- NOP9 | c.112del p.Q38Nfs*20 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- RAD54B | c.10T>A p.S4T | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SYT16 | c.978dup p.M327Hfs*27 | Frame Shift Ins (INS) | VAF 49/114 reads (43%) | called by mutect2, pindel, varscan2
- APOB | c.10056C>A p.T3352= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as rs369022661; ClinVar: likely benign; called by muse, mutect2, varscan2
- KAT6A | c.3436T>C p.L1146= | Silent (SNP) | VAF 40/238 reads (17%) | called by muse, mutect2, varscan2
- LZTS3 | c.861G>A p.S287= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs768101491; called by muse, mutect2, varscan2
- UGT3A2 | c.696C>T p.G232= | Silent (SNP) | VAF 38/87 reads (44%) | called by muse, mutect2, varscan2
